Somatic mutation profile of tumor specimen TCGA-63-A5MM-01A (aliquot TCGA-63-A5MM-01A-11D-A26M-08) from TCGA case TCGA-63-A5MM, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19b2caf2-3cf0-4553-943f-b46fd335b7e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MM-10A (Blood Derived Normal), aliquot TCGA-63-A5MM-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eca5613c-1ecf-4c99-b7a9-3cfcd6aaf12f

The open-access MAF lists 1,321 somatic variants for this specimen: 1,001 protein-altering or splice-affecting, 295 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 811, Silent 295, Frame Shift Del 110, Nonsense Mutation 35, Frame Shift Ins 23, Intron 13, Splice Site 12, In Frame Del 5, RNA 5, Splice Region 4, 5'UTR 3, 3'Flank 2.

Variants (750 of 1,321; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as CM002273, COSV55670863; called by muse, mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TMPRSS3 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs137853000, CM054158, CM1513228; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13375G>A p.A4459T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101291264; called by muse, mutect2, varscan2
- ABCA2 | c.5263C>T p.R1755C (on ENST00000614293; = p.R1725C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1362222609, COSV55802414; called by muse, mutect2, varscan2
- ABCA4 | c.6512T>A p.I2171N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV100933073; called by muse, mutect2, varscan2
- ABCA6 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144484556; called by muse, mutect2, varscan2
- ABCA7 | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54026688; called by muse, mutect2, varscan2
- ABCA7 | c.5804C>T p.A1935V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1468750791, COSV54023786; called by muse, mutect2
- ABCA8 | c.1030C>A p.L344M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV99285262; called by muse, mutect2, varscan2
- ABCC12 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs374228610, COSV100252371, COSV60912597; called by muse, mutect2, varscan2
- ABCC2 | c.2354A>T p.D785V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100966439; called by muse, mutect2, varscan2
- ABCC3 | c.3161G>A p.R1054H | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1254184775, COSV99558922; called by muse, mutect2, varscan2
- ABCD4 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.037); catalogued as COSV100084140; called by muse, mutect2
- ABCG8 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99699595; called by muse, mutect2, varscan2
- ABI3BP | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV52532003, COSV52544958, COSV99425928; called by muse, mutect2, varscan2
- ABTB2 | c.1337A>C p.D446A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100130965; called by muse, mutect2, varscan2
- AC098582.1 | c.2295T>A p.N765K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV99985423; called by muse, mutect2, varscan2
- ACACB | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs201408408; called by muse, mutect2, varscan2
- ACAN | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100717537; called by muse, mutect2, varscan2
- ACE | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs762056936, COSV52011646; called by muse, mutect2, varscan2
- ACOX3 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV100711880; called by muse, mutect2, varscan2
- ACTR5 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV54761268; called by muse, mutect2, varscan2
- ACTRT1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs185459023, COSV100947479; called by muse, mutect2, varscan2
- ADAM21 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV50788685, COSV99960720; called by muse, mutect2, varscan2
- ADAM7 | c.2109-1G>A p.X703_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV51535419; called by muse, mutect2
- ADAMTS3 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99710631; called by muse, mutect2
- ADAMTSL3 | c.3743T>A p.I1248K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99717785; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100416348; called by muse, mutect2, varscan2
- ADD1 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV53272489, COSV99296196; called by muse, mutect2, varscan2
- ADGRG7 | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1019869787, COSV99840748; called by muse, mutect2, varscan2
- ADGRV1 | c.9209A>G p.D3070G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV101315679; called by muse, mutect2, varscan2
- ADORA1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs139946190, COSV55141873; called by muse, mutect2, varscan2
- ADRA1B | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs758643818, COSV60700741; called by muse, mutect2, varscan2
- ADRA1D | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs147522815, COSV101062939; called by mutect2, varscan2
- AEBP1 | c.1505A>T p.D502V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99788586; called by muse, mutect2, varscan2
- AFDN | c.5312G>A p.R1771H (on ENST00000447894 / NM_001366320.1; = p.R1690H on NM_001207008.1) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs759403576, COSV100652728; called by muse, mutect2
- AFF2 | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649535; called by muse, mutect2, varscan2
- AHCTF1 | c.4198G>A p.A1400T (on ENST00000366508; = p.A1374T on NM_015446.5) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs751891708, COSV100403385; called by mutect2, varscan2
- AHNAK | c.11317G>A p.D3773N | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV99946461; called by muse, mutect2, varscan2
- AKAP12 | c.187T>A p.S63T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99482833; called by muse, mutect2, varscan2
- AKAP17A | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs771306611, COSV58309714; called by muse, mutect2, varscan2
- AKR1B1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1229108905, COSV53646458; called by muse, mutect2, varscan2
- AL121899.2 | c.800G>T p.R267M | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV101198422; called by muse, mutect2
- ALK | c.3700G>A p.A1234T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66574878; called by muse, mutect2, varscan2
- AMD1 | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV100924467; called by muse, mutect2, varscan2
- AMER2 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100766179; called by muse, mutect2
- AMPD3 | c.959C>T p.A320V (on ENST00000396553 / NM_001025389.2; = p.A329V on NM_000480.3) | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs147542803, CM940054; called by muse, mutect2, varscan2
- ANKRD23 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs370284092; called by mutect2, varscan2
- ANKRD27 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV100042652; called by muse, varscan2
- ANKRD30A | c.567A>T p.E189D (on ENST00000611781; = p.E133D on NM_052997.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1360578397, COSV64611137, COSV64615505; called by mutect2, varscan2
- ANKZF1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.274); catalogued as COSV99850392; called by muse, mutect2, varscan2
- ANPEP | c.1879A>G p.T627A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV55594503; called by muse, mutect2
- AOAH | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99332430; called by muse, mutect2, varscan2
- AP1B1 | c.2695T>A p.S899T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100434477; called by muse, mutect2, varscan2
- AP1B1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370184347; called by muse, mutect2, varscan2
- AP2M1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs1431035134, COSV53047259; called by muse, mutect2, varscan2
- AP3M1 | c.730T>A p.S244T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV100786685; called by muse, mutect2, varscan2
- AP3M1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs924000710, COSV100786687; called by muse, mutect2, varscan2
- AP4E1 | c.2389T>A p.S797T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV99956443; called by muse, mutect2, varscan2
- APC | c.8162G>A p.R2721H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs587780606, COSV57383058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs749308859, COSV99264638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOL3 | c.248C>T p.A83V (on ENST00000349314 / NM_145640.2; = p.A12V on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100652038; called by muse, mutect2, varscan2
- ARAP3 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.644); catalogued as rs763210159, COSV53350011; called by mutect2, varscan2
- AREL1 | c.481+1G>A p.X161_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV62667358; called by muse, mutect2, varscan2
- ARFGEF2 | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100904136; called by muse, mutect2, varscan2
- ARHGAP39 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99430638; called by muse, mutect2, varscan2
- ARHGEF15 | c.1949del p.G650Afs*145 | Frame Shift Del (DEL) | VAF 34/228 reads (15%) | catalogued as COSV62725865; called by mutect2, varscan2
- ARHGEF40 | c.4126G>A p.A1376T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.241); catalogued as COSV100070181; called by muse, mutect2
- ARID1B | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771056710, COSV99268185; called by muse, mutect2, varscan2
- ARSG | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1214710312, COSV50929925; called by muse, mutect2
- ARSI | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100155941; called by muse, mutect2, varscan2
- ASAP3 | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV60875047; called by muse, mutect2
- ASXL1 | c.3283T>C p.S1095P | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100038353; called by muse, mutect2, varscan2
- ATAD5 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV100429788; called by muse, mutect2, varscan2
- ATF3 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1440141536, COSV100421985; called by muse, mutect2, varscan2
- ATF7IP | c.65A>T p.D22V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99661377; called by muse, mutect2, varscan2
- ATG16L2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as COSV100352222; called by muse, mutect2
- ATG7 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100607012; called by muse, mutect2, varscan2
- ATM | c.3082C>G p.L1028V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1263930458, COSV99588630; ClinVar: uncertain significance; called by muse, mutect2
- ATP1A2 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755353911, COSV63401911; called by muse, mutect2, varscan2
- ATP1A4 | c.2672G>A p.G891D | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100927479, COSV63627281; called by muse, mutect2, varscan2
- ATP23 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs181118426; called by muse, mutect2, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 33/169 reads (20%) | catalogued as rs782513834; called by pindel, varscan2
- ATP4A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs200588214, COSV99077886; called by muse, mutect2, varscan2
- ATP6V1A | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56361181; called by muse, mutect2, varscan2
- B4GALNT4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.353); catalogued as COSV57327208; called by muse, mutect2, varscan2
- BAAT | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs772876970, COSV99408422; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs771098505; called by mutect2, varscan2
- BARD1 | c.1864C>T p.L622F | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99638291; called by muse, mutect2
- BBS9 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs547643751, COSV54164830; called by muse, mutect2, varscan2
- BCAR1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV99366303; called by muse, mutect2
- BCHE | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV100012302; called by muse, mutect2, varscan2
- BCL9 | c.1026dup p.T343Hfs*34 | Frame Shift Ins (INS) | VAF 18/163 reads (11%) | catalogued as rs1553204401; called by mutect2, pindel, varscan2
- BCL9L | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52685927; called by muse, mutect2, varscan2
- BEST1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99861255; called by muse, mutect2, varscan2
- BICRA | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.203); catalogued as COSV101194262, COSV67604279; called by muse, mutect2, varscan2
- BMP6 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs377711135; called by muse, mutect2, varscan2
- BMP8B | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs141647099; called by muse, mutect2, varscan2
- BMPR2 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV101001378; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNIP5 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs368024556; called by muse, mutect2, varscan2
- BOD1L1 | c.5102C>G p.S1701C | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99238890, COSV99239260; called by muse, mutect2
- BPIFB1 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99487278; called by muse, mutect2, varscan2
- BRD8 | c.2387T>C p.M796T (on ENST00000254900 / NM_139199.2; = p.M869T on NM_006696.4) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99136753; called by muse, mutect2, varscan2
- BRPF1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs754862321, COSV57406187; called by muse, mutect2, varscan2
- BTAF1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs780477587, COSV99795118; called by mutect2, varscan2
- BTAF1 | c.3405A>C p.K1135N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as COSV99795120; called by muse, mutect2, varscan2
- C12orf43 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs758998918, COSV99982354; called by muse, mutect2, varscan2
- C17orf97 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as rs373476599; called by muse, mutect2, varscan2
- C1R | c.773A>G p.D258G (on ENST00000536053 / NM_001354346.2; = p.D244G on NM_001733.7) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101599216; called by muse, mutect2, varscan2
- C3AR1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.763); catalogued as COSV99368280; called by muse, mutect2, varscan2
- C3orf70 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100621178; called by muse, mutect2, varscan2
- C4A | c.3442G>A p.A1148T | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs767169624, COSV71179250; called by muse, mutect2, varscan2
- C8B | c.1163C>A p.A388D | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV64777804; called by muse, mutect2, varscan2
- CA11 | c.838A>T p.I280F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV99320550; called by muse, mutect2, varscan2
- CA4 | c.191A>T p.D64V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99958269; called by muse, mutect2, varscan2
- CACHD1 | c.3547C>T p.R1183C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs756541202, COSV51550217; called by muse, mutect2, varscan2
- CACNA1A | c.4813A>G p.N1605D | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV100801735; called by muse, mutect2, varscan2
- CACNA1B | c.3496G>A p.A1166T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs554281635, COSV53139337; called by muse, mutect2, varscan2
- CACNA1G | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776457023, COSV100661456; called by muse, mutect2, varscan2
- CACNG2 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100268660; called by muse, mutect2, varscan2
- CAD | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs368446772; called by muse, mutect2, varscan2
- CADM1 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV100522397; called by muse, mutect2, varscan2
- CAND1 | c.2795T>G p.I932S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV101607307; called by muse, mutect2, varscan2
- CAPN13 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs201062209, COSV99699998; called by muse, mutect2, varscan2
- CAPN7 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781081400, COSV53779852; called by muse, mutect2, varscan2
- CASQ1 | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100927260, COSV63624500; called by muse, mutect2, varscan2
- CASZ1 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as COSV100681024, COSV100682248; called by muse, mutect2, varscan2
- CCN4 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99137009; called by muse, mutect2, varscan2
- CCND1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57121200, COSV57123646; called by muse, mutect2, varscan2
- CCNF | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs1428900926, COSV53539584; called by muse, mutect2, varscan2
- CCT5 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99725194; called by muse, varscan2
- CCT6A | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV51905537; called by muse, mutect2, varscan2
- CCT6A | c.820del p.I274* | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs1482449902; called by mutect2, pindel, varscan2
- CCT6B | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100030545; called by muse, mutect2, varscan2
- CD163L1 | c.1173G>A p.W391* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100549859; called by muse, mutect2, varscan2
- CD247 | c.463G>A p.A155T (on ENST00000362089 / NM_198053.3; = p.A154T on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs561262982, COSV54816287; called by muse, mutect2, varscan2
- CD276 | c.1346C>T p.A449V (on ENST00000318443 / NM_001024736.2; = p.A231V on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); catalogued as rs775147523, COSV100573323; called by muse, mutect2, varscan2
- CD2BP2 | c.350A>C p.D117A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV99977011; called by muse, mutect2
- CD68 | c.766A>T p.T256S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV99548830; called by muse, mutect2, varscan2
- CDC42BPB | c.1069T>C p.Y357H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775320; called by muse, mutect2, varscan2
- CDH1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.244); catalogued as COSV55738577; called by muse, mutect2, varscan2
- CDH10 | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100050696, COSV52576717; called by muse, mutect2, varscan2
- CDH18 | c.1575C>G p.F525L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs758485322, COSV56909920, COSV56963942, COSV99933256; called by mutect2, varscan2
- CDH26 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 25/194 reads (13%) | catalogued as COSV99722116; called by muse, mutect2, varscan2
- CDH5 | c.1820G>A p.C607Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100439123; called by muse, mutect2, varscan2
- CDH9 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346865409, COSV50303173, COSV50488057; called by muse, mutect2, varscan2
- CDHR2 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.754); catalogued as rs200126955; called by muse, mutect2, varscan2
- CDK5RAP3 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs1490985530, COSV58114979; called by muse, mutect2, varscan2
- CEACAM5 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.036); catalogued as COSV99703809; called by muse, mutect2, varscan2
- CEACAM8 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200797632, COSV99747336; called by muse, mutect2, varscan2
- CELSR1 | c.6460C>T p.R2154C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs371148961; called by muse, mutect2, varscan2
- CELSR1 | c.3673G>A p.A1225T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1423266653, COSV99417506; called by muse, mutect2, varscan2
- CEMIP | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs540926515, COSV54991164; called by muse, mutect2, varscan2
- CENPJ | c.2167A>G p.R723G | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs989387440, COSV101121479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPU | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs372424575; called by muse, mutect2, varscan2
- CEP350 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100658280; called by muse, mutect2
- CERK | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1228637854, COSV99348499; called by muse, mutect2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP65 | c.3775T>C p.Y1259H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.54); catalogued as COSV100444871; called by muse, mutect2
- CGNL1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs779469261, COSV99847848; called by muse, mutect2, varscan2
- CHD6 | c.739T>A p.Y247N | Missense Mutation (SNP) | VAF 86/344 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100497970; called by muse, mutect2, varscan2
- CHD8 | c.5369C>T p.A1790V (on ENST00000646647 / NM_001170629.2; = p.A1511V on NM_020920.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100765266; called by muse, mutect2, varscan2
- CHD8 | c.1440A>G p.I480M (on ENST00000646647 / NM_001170629.2; = p.I201M on NM_020920.4) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101303075; called by muse, mutect2, varscan2
- CHERP | c.2492C>A p.A831E | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV52222414, COSV99550116; called by muse, mutect2, varscan2
- CHMP1A | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs767659184, COSV99498312; called by muse, mutect2, varscan2
- CHRNA3 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.034); catalogued as rs1340001277, COSV100468073; called by muse, mutect2, varscan2
- CHRNA6 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV99373132; called by muse, mutect2, varscan2
- CHST15 | c.1467G>A p.M489I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.137); catalogued as COSV100655026; called by muse, mutect2, varscan2
- CIAO3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs777141563, COSV52400662; called by muse, mutect2, varscan2
- CILP | c.3080T>A p.V1027D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99973057; called by muse, mutect2, varscan2
- CIR1 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as COSV100564924; called by muse, mutect2
- CIT | c.5365G>T p.V1789L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV99948952; called by muse, mutect2, varscan2
- CLCN2 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99658380; called by muse, mutect2, varscan2
- CLDN12 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs1442500935, COSV99842038; called by muse, mutect2, varscan2
- CLEC18B | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs775538259, COSV100375838; called by mutect2, varscan2
- CLSTN3 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs988948667, COSV56934226; called by muse, mutect2
- CLUL1 | c.1152G>T p.W384C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100620952; called by muse, mutect2, varscan2
- CNFN | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1187237917, COSV99706157; called by muse, mutect2, varscan2
- CNOT6L | c.50G>A p.R17H (on ENST00000504123 / NM_001286790.2; = p.R12H on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs1478808427, COSV99361577; called by muse, mutect2
- CNTN5 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54276018, COSV99674889; called by muse, mutect2, varscan2
- CNTROB | c.2612G>A p.R871H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs538266374, COSV100972624; called by muse, mutect2, varscan2
- COL22A1 | c.4361T>C p.L1454P | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV100277291; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 7/27 reads (26%) | catalogued as rs760493024; called by mutect2, varscan2
- COL27A1 | c.1568T>C p.V523A | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100620857; called by muse, mutect2, varscan2
- COL4A1 | c.654A>G p.G218= | Splice Region (SNP) | VAF 13/78 reads (17%) | catalogued as COSV101011033; called by muse, mutect2, varscan2
- COL4A2 | c.3854C>T p.A1285V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.19); catalogued as rs753148213, COSV64627837; called by muse, mutect2, varscan2
- COL4A2 | c.4376G>A p.G1459D | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847291; called by muse, mutect2, varscan2
- COL4A4 | c.4970C>T p.A1657V | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100306489; called by muse, mutect2, varscan2
- COL6A3 | c.5621G>T p.R1874M | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV55113691, COSV99797060; called by muse, mutect2, varscan2
- COL6A3 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369379463, COSV55093992; called by muse, mutect2, varscan2
- COL9A1 | c.1178del p.P393Lfs*36 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | catalogued as rs1482734025, COSV57884567; called by mutect2, pindel
- COPG1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59114478; called by muse, mutect2, varscan2
- CPZ | c.1879G>A p.A627T (on ENST00000360986 / NM_001014447.3; = p.A616T on NM_003652.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100248861; called by muse, mutect2, varscan2
- CRB3 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs754598571, COSV100375241; called by muse, mutect2, varscan2
- CROT | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs773304654, COSV100519440; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1594dup p.T532Nfs*31 | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | catalogued as rs778908076; called by mutect2, varscan2
- CST5 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs771464838, COSV59013838; called by muse, mutect2, varscan2
- CTAGE1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs372035129; called by muse, mutect2, varscan2
- CTDP1 | c.2826C>A p.S942R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99310321; called by muse, mutect2, varscan2
- CTR9 | c.3271T>A p.S1091T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100797300; called by muse, mutect2, varscan2
- CTTNBP2 | c.659G>T p.S220I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV99353472; called by muse, mutect2, varscan2
- CXCL17 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV59409726; called by muse, mutect2, varscan2
- CYCS | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs367666281; called by muse, mutect2, varscan2
- CYP26B1 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99134395; called by muse, mutect2, varscan2
- CYP4F11 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs550803822, COSV56128101, COSV99930731; called by muse, mutect2, varscan2
- CYTIP | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV99938687; called by muse, mutect2
- DAGLA | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV99944166; called by muse, mutect2, varscan2
- DCHS1 | c.1506A>C p.Q502H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100201809; called by muse, mutect2
- DCHS1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV55034262, COSV55039579; called by muse, mutect2, varscan2
- DCLK1 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as COSV55174599, COSV55205136; called by muse, mutect2, varscan2
- DCST1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs958801714, COSV55062127; called by muse, mutect2, varscan2
- DCT | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 35/234 reads (15%) | catalogued as COSV100986159, COSV100986326; called by muse, mutect2, varscan2
- DCTN4 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267503727, COSV69782535; called by muse, mutect2, varscan2
- DDIT3 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765891803, COSV100007202; called by muse, mutect2, varscan2
- DDX39A | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs141207973; called by muse, mutect2, varscan2
- DDX54 | c.2552C>G p.S851C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV100013713; called by muse, mutect2, varscan2
- DDX55 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99434317; called by muse, mutect2, varscan2
- DFFB | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs375484294; called by muse, mutect2, varscan2
- DHRS1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as rs747329375, COSV55383365; called by muse, mutect2, varscan2
- DHX9 | c.1142T>A p.I381N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); catalogued as COSV100841317; called by muse, mutect2, varscan2
- DISP3 | c.3481C>T p.R1161C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1177151755, COSV99607937; called by muse, mutect2, varscan2
- DMXL1 | c.7934C>T p.A2645V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60719530; called by muse, mutect2
- DNAH1 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101325190; called by muse, mutect2, varscan2
- DNAH1 | c.3305G>A p.R1102H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as rs746027255, COSV70232154; called by muse, mutect2, varscan2
- DNAH9 | c.10123A>G p.T3375A | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV99305006; called by muse, varscan2
- DNAJB7 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99344055; called by muse, mutect2
- DNMT3B | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1267164985, COSV52416625, COSV52424854; called by muse, mutect2, varscan2
- DOCK1 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1473310885, COSV99728178; called by muse, mutect2, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as rs1559599687; called by mutect2, pindel, varscan2
- DOCK8 | c.777T>A p.C259* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs531488965, COSV101210202; called by muse, mutect2, varscan2
- DOCK8 | c.5767C>T p.H1923Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV101209870; called by muse, mutect2, varscan2
- DPH1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs767417481, COSV53985426; called by mutect2, varscan2
- DRAXIN | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610632; called by muse, mutect2, varscan2
- DRC1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs760707903, COSV56532219; called by muse, mutect2, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2, varscan2
- DRICH1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.913); catalogued as rs775895089, COSV58503806; called by muse, mutect2, varscan2
- DSCAM | c.6016G>A p.A2006T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs781716602, COSV68028967; called by muse, mutect2, varscan2
- DST | c.18506C>T p.A6169V (on ENST00000361203 / NM_001374722.1; = p.A3866V on NM_015548.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs766294952, COSV99753298; called by muse, mutect2
- DST | c.1223G>T p.G408V (on ENST00000361203 / NM_001374722.1; = p.G82V on NM_001723.6) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55000055, COSV99753308; called by muse, mutect2
- DYNC1H1 | c.7928G>A p.R2643H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100794663, COSV64137932; called by muse, mutect2, varscan2
- DYSF | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.066); catalogued as rs748392752, COSV50297914; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs369293935; called by mutect2, varscan2
- EDC4 | c.4097G>A p.R1366H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs1413981973, COSV100197561; called by muse, mutect2, varscan2
- EIF3A | c.662A>T p.N221I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100974550; called by muse, mutect2, varscan2
- ELAC2 | c.1195del p.L399Cfs*49 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV62032339; called by mutect2, pindel, varscan2
- ELAPOR2 | c.2102G>A p.G701D (on ENST00000450689 / NM_001142749.3; = p.G534D on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51885828; called by muse, mutect2, varscan2
- ELAPOR2 | c.747G>A p.M249I (on ENST00000450689 / NM_001142749.3; = p.M82I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs764550031, COSV99788478; called by muse, mutect2, varscan2
- ELAVL3 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV100820716; called by muse, mutect2, varscan2
- ELAVL4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs200396874, COSV100836643; called by muse, mutect2, varscan2
- ELMO2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs780710246, COSV99281541; called by mutect2, varscan2
- EMC1 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs869320625, CM162577, COSV100617458; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- EMC9 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs768382173, COSV99246116; called by muse, mutect2, varscan2
- ENOSF1 | c.361G>A p.A121T (on ENST00000340116 / NM_001354066.2; = p.A73T on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs374563667; called by muse, mutect2
- EPHA2 | c.1682+1G>C p.X561_splice | Splice Site (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100626053; called by muse, mutect2
- EPHA2 | c.758G>T p.W253L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100626054; called by muse, varscan2
- EPHA6 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101061486; called by muse, mutect2, varscan2
- EPHB1 | c.415A>T p.T139S | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101212897; called by muse, mutect2
- EPHB4 | c.2243T>C p.V748A | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100639451; called by muse, mutect2, varscan2
- EPS8L3 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100719683; called by muse, mutect2, varscan2
- ERC2 | c.2552T>A p.I851N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99882757; called by muse, mutect2, varscan2
- ERCC1 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50004163, COSV99185243; called by muse, mutect2
- ESPL1 | c.4046C>A p.P1349H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99229075; called by muse, mutect2, varscan2
- ESRRB | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV99835015; called by muse, mutect2, varscan2
- ESRRB | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV99835017; called by muse, mutect2, varscan2
- EVA1B | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54633569; called by muse, mutect2, varscan2
- EXOC8 | c.184A>G p.N62D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1452812693, COSV99149601; called by muse, mutect2
- EXOSC5 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs201243873, COSV99652620; called by muse, mutect2, varscan2
- F13A1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.844); catalogued as rs529985469, COSV99342352, COSV99343273; called by muse, mutect2, varscan2
- F2RL1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56996639; called by muse, mutect2, varscan2
- FAAP20 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1279791871, COSV101051962; called by muse, mutect2, varscan2
- FABP9 | c.255A>G p.I85M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV100986932; called by muse, mutect2, varscan2
- FAM110B | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs764848330, COSV100826082; called by muse, mutect2, varscan2
- FAM117A | c.369G>A p.T123= | Splice Region (SNP) | VAF 4/34 reads (12%) | catalogued as rs774309596, COSV53630870; called by muse, mutect2
- FAM160A2 | c.1784G>A p.R595H (on ENST00000449352 / NM_001098794.2; = p.R609H on NM_032127.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs562285223, COSV99791885; called by muse, mutect2
- FAP | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99501995; called by muse, mutect2, varscan2
- FARP2 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1042074629, COSV99884264; called by muse, varscan2
- FAT1 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs536104649, COSV71674334; called by muse, mutect2, varscan2
- FAT1 | c.1490A>T p.Y497F | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.093); catalogued as COSV101499189; called by muse, mutect2, varscan2
- FBH1 | c.446G>A p.R149Q (on ENST00000362091 / NM_178150.3; = p.R200Q on NM_032807.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1208269688, COSV100758667; called by muse, mutect2, varscan2
- FBH1 | c.2588A>T p.D863V (on ENST00000362091 / NM_178150.3; = p.D914V on NM_032807.4) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100758668; called by muse, mutect2
- FBL | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99695229; called by muse, mutect2, varscan2
- FBXL4 | c.1063A>T p.T355S | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.956); catalogued as COSV100013961; called by muse, mutect2, varscan2
- FBXO27 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs770250225, COSV53072390; called by muse, mutect2, varscan2
- FBXO3 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV99682126; called by muse, mutect2, varscan2
- FEM1C | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as rs867826723, COSV99174363; called by muse, mutect2, varscan2
- FKBP15 | c.331A>T p.I111F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99438459; called by muse, mutect2, varscan2
- FKBP5 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs369848186; called by muse, mutect2, varscan2
- FLG | c.5540C>T p.T1847M | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs766634595, COSV64242677, COSV64244514; called by muse, mutect2
- FLG2 | c.2935T>C p.S979P | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs879093874, COSV101165717; called by muse, mutect2
- FLNA | c.7889T>A p.V2630D (on ENST00000369850 / NM_001110556.2; = p.V2622D on NM_001456.3) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774443; called by muse, mutect2, varscan2
- FLRT3 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV99429198; called by muse, mutect2, varscan2
- FLT4 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV56097004; called by muse, mutect2, varscan2
- FNTA | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100172465; called by muse, mutect2, varscan2
- FOXB2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277482340, COSV65022737; called by muse, mutect2, varscan2
- FOXE1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421696257, COSV100909870; called by muse, mutect2, varscan2
- FOXF2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.207); catalogued as COSV52527653; called by muse, mutect2, varscan2
- FOXN3 | c.839C>T p.A280V (on ENST00000261302; = p.A258V on NM_005197.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs201672702, COSV54312866; called by muse, mutect2
- FRAS1 | c.9257G>A p.G3086D | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349981; called by muse, mutect2, varscan2
- FRMPD4 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV101042498; called by muse, mutect2, varscan2
- FSD2 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100575073; called by muse, mutect2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as rs781034813; called by mutect2, pindel
- G6PC3 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs145779116; called by muse, mutect2, varscan2
- GABBR2 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1342775753, COSV52312455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRB2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99195793; called by muse, mutect2, varscan2
- GABRD | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.278); catalogued as rs200862446, COSV66081405; called by muse, mutect2, varscan2
- GAPDHS | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as rs750502242, COSV55880079; called by muse, mutect2, varscan2
- GAREM1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748897383, COSV52515818; called by muse, mutect2, varscan2
- GAS8 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs145845004; called by muse, mutect2, varscan2
- GASK1B | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV99647444; called by muse, mutect2, varscan2
- GATA2 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs374457534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATAD2A | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768273089, COSV53068416; called by muse, mutect2, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | catalogued as rs755348339; called by mutect2, pindel, varscan2
- GCDH | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99535803; called by muse, mutect2, varscan2
- GCNT1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs142199715; called by muse, mutect2, varscan2
- GDAP2 | c.1248-1G>T p.X416_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV101031892; called by muse, mutect2, varscan2
- GEMIN5 | c.1995G>T p.Q665H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99593770; called by muse, mutect2, varscan2
- GFRA3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as rs867556640, COSV99218327; called by muse, mutect2, varscan2
- GGT7 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as COSV100321837; called by muse, mutect2, varscan2
- GIGYF1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs780767946, COSV99308872; called by muse, mutect2, varscan2
- GIGYF1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs1402450453, COSV99308780; called by muse, mutect2
- GIGYF2 | c.3416G>A p.C1139Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101004180; called by muse, mutect2
- GIMAP8 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs772996358, COSV56229974; called by muse, mutect2, varscan2
- GIP | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.992); catalogued as COSV100656925; called by muse, mutect2, varscan2
- GIPC1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs146515353; called by mutect2, varscan2
- GLG1 | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.759); catalogued as COSV99215503, COSV99215541; called by muse, mutect2, varscan2
- GMIP | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV52558927, COSV99179144; called by muse, mutect2, varscan2
- GNL2 | c.1353G>A p.W451* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100894972; called by muse, mutect2
- GNL3 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99803669; called by muse, mutect2, varscan2
- GPC2 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52783809; called by muse, mutect2, varscan2
- GPD1L | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99245616; called by muse, mutect2, varscan2
- GPR176 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100137075; called by mutect2, varscan2
- GPR6 | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99254110; called by muse, mutect2, varscan2
- GPRC5A | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50008881; called by muse, mutect2, varscan2
- GPRIN1 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs1243986293, COSV99991287; called by muse, mutect2, varscan2
- GPRIN3 | c.1791A>C p.R597S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV100310654; called by muse, mutect2, varscan2
- GPX7 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100790915; called by muse, mutect2
- GRIN2A | c.4115G>T p.R1372M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV100409083; called by muse, mutect2, varscan2
- GRK7 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV99379688; called by muse, mutect2, varscan2
- GSS | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.082); catalogued as COSV99404313; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as COSV54945907; called by mutect2, varscan2
- H2AC16 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100511163; called by muse, mutect2
- H2AC8 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99773130; called by muse, mutect2, varscan2
- H2BU1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as rs767814492, COSV100797262; called by muse, mutect2, varscan2
- HABP4 | c.1203del p.N402Tfs*95 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs1564171810; called by mutect2, pindel, varscan2
- HAPLN1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773994130, COSV99164506; called by muse, mutect2, varscan2
- HDAC1 | c.806A>T p.D269V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100269528; called by muse, mutect2, varscan2
- HIP1 | c.560A>T p.E187V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417225; called by muse, mutect2
- HIPK1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV101060279; called by muse, mutect2, varscan2
- HIPK3 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs556300403, COSV57561507; called by muse, mutect2, varscan2
- HK3 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs541590139, COSV52840834; called by muse, mutect2, varscan2
- HMGCR | c.1772G>A p.G591D | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99843130; called by muse, mutect2, varscan2
- HMX3 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs780954487, COSV100774134; called by muse, varscan2
- HNF1A | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1421619915, COSV56567444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPH3 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1341725930, COSV99769182; called by muse, mutect2
- HOOK1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1363806894, COSV100969029; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1312599377, COSV52375380; called by muse, mutect2
- HS6ST1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1225549801, COSV52127142; called by muse, mutect2, varscan2
- HSD11B2 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs768979343, COSV99341036; called by muse, mutect2, varscan2
- HSPA1L | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs775401949, COSV65150401; called by muse, mutect2, varscan2
- HSPA2 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.042); catalogued as COSV99904799; called by muse, mutect2
- HSPA8 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV99914297; called by muse, mutect2
- HUS1B | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100033281; called by muse, mutect2, varscan2
- HUWE1 | c.11354C>T p.A3785V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as COSV53366993; called by muse, mutect2, varscan2
- ICAM5 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV55747481; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel
- IFITM3 | c.26_28del p.F9del | In Frame Del (DEL) | VAF 28/257 reads (11%) | catalogued as rs1294836415; called by pindel, varscan2
- IGF2BP1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV99288434; called by muse, mutect2, varscan2
- IGF2BP1 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51729898, COSV99288437, COSV99288540; called by muse, mutect2, varscan2
- IGFLR1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV53077058; called by muse, mutect2
- IGLV2-14 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.087); catalogued as rs369431674; called by muse, mutect2, varscan2
- IL20RB | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100291004; called by muse, mutect2, varscan2
- INKA2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.255); catalogued as rs1266917083, COSV61878400; called by muse, mutect2, varscan2
- IPMK | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV64243565; called by muse, mutect2, varscan2
- IQCN | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV101148492; called by muse, mutect2, varscan2
- IQSEC3 | c.1819G>A p.A607T (on ENST00000538872 / NM_001170738.2; = p.A304T on NM_015232.1) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as rs752727349, COSV100406787; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs761880048; called by mutect2, varscan2
- ITFG1 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs761660313, COSV100278527; called by muse, mutect2
- ITPKA | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99540708; called by muse, mutect2, varscan2
- ITPR3 | c.4945C>A p.Q1649K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV100967161; called by muse, mutect2, varscan2
- JAKMIP3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374779116; called by muse, mutect2, varscan2
- JAKMIP3 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs1273401007, COSV100059955, COSV53819847; called by muse, mutect2, varscan2
- JPH3 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs375201712; called by muse, mutect2, varscan2
- KANK2 | c.1828G>A p.A610T (on ENST00000586659 / NM_001379562.1; = p.A618T on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV62006258; called by muse, mutect2, varscan2
- KANSL3 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62622157; called by muse, mutect2, varscan2
- KAT6B | c.4249G>T p.E1417* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99767639; called by muse, mutect2, varscan2
- KBTBD13 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs746735951, COSV101416687; called by muse, varscan2
- KCNAB2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs778196788, COSV51237422; called by muse, mutect2, varscan2
- KCNG3 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100044875; called by muse, mutect2, varscan2
- KCNJ12 | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100056159, COSV59169118; called by muse, mutect2, varscan2
- KCNK17 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs191023425, COSV64678206; called by muse, mutect2, varscan2
- KCNK5 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV63989182; called by muse, mutect2, varscan2
- KCNMA1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54271266; called by muse, mutect2
- KCTD10 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs1434330317, COSV57326715; called by muse, mutect2
- KDM4C | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs758317571, COSV101184751; called by muse, mutect2, varscan2
- KDM5B | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1236674068, COSV52511996; called by muse, mutect2, varscan2
- KDM6A | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs772197961, COSV65036859, COSV65039510; called by mutect2, varscan2
- KERA | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899368; called by muse, mutect2, varscan2
- KHK | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99565921; called by muse, mutect2
- KIAA1614 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs751648938, COSV100851173; called by muse, mutect2, varscan2
- KIF19 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as COSV100739011; called by muse, mutect2
- KIF1B | c.2986G>A p.V996I (on ENST00000377086 / NM_001365952.1; = p.V950I on NM_015074.3) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs145596547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1C | c.2948G>A p.S983N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100297029; called by muse, mutect2, varscan2
- KIZ | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs181816823, COSV99851971; called by muse, mutect2, varscan2
- KLB | c.2365T>C p.Y789H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV99962037; called by muse, mutect2, varscan2
- KLHL31 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1310987990, COSV100911754; called by muse, mutect2, varscan2
- KLHL34 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV101069893; called by muse, mutect2, varscan2
- KLHL34 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV101069894; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | catalogued as COSV52930337; called by mutect2, varscan2
- KLHL42 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV101179715; called by muse, mutect2, varscan2
- KLHL6 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757613109, COSV100384379; called by muse, mutect2, varscan2
- KLK11 | c.770C>T p.A257V (on ENST00000594768 / NM_144947.3; = p.A225V on NM_006853.3) | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs759848513, COSV100011003; called by muse, mutect2, varscan2
- KMT2D | c.15545del p.G5182Afs*61 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | catalogued as COSV56464242; called by mutect2, pindel, varscan2
- KMT2D | c.3151G>A p.V1051I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1229315707, COSV56435574, COSV56496634; called by muse, mutect2, varscan2
- KMT5C | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1222888821, COSV55319690; called by muse, mutect2, varscan2
- KNDC1 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100463997; called by muse, mutect2, varscan2
- KREMEN1 | c.372G>T p.K124N (on ENST00000407188; = p.K126N on NM_032045.5) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.721); catalogued as COSV100588626, COSV100588639; called by muse, mutect2, varscan2
- KREMEN1 | c.1094G>A p.S365N (on ENST00000407188; = p.S367N on NM_032045.5) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as COSV100588627; called by muse, mutect2, varscan2
- KRT1 | c.1789G>A p.G597S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs1469539692, COSV52867649; called by muse, mutect2, varscan2
- KRT6B | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.13); catalogued as COSV99360580; called by muse, mutect2
- KRT73 | c.1022A>G p.D341G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988384; called by muse, mutect2, varscan2
- KRT75 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs368924328; called by mutect2, varscan2
- KRTAP10-4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs782611665, COSV100552532; called by muse, mutect2, varscan2
- KRTAP10-7 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs1397064711, COSV100170360; called by muse, mutect2, varscan2
- KRTAP5-8 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as rs574501468, COSV101273122; called by muse, mutect2, varscan2
- LAMA4 | c.3302A>G p.E1101G (on ENST00000230538 / NM_001105206.3; = p.E1094G on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100037954; called by muse, mutect2
- LAMA5 | c.2848G>C p.E950Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.518); catalogued as COSV99438872; called by muse, mutect2
- LCE2C | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.953); catalogued as COSV100909410; called by muse, mutect2, varscan2
- LGR6 | c.2293G>A p.A765T (on ENST00000367278 / NM_001017403.1; = p.A713T on NM_021636.3) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV99706468; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 32/91 reads (35%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMBR1 | c.1187T>G p.V396G | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100626607; called by muse, mutect2
- LMTK3 | c.2783T>C p.V928A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99540193; called by muse, mutect2
- LMX1A | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as COSV99671924; called by muse, mutect2, varscan2
- LMX1A | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.076); catalogued as COSV99671926; called by muse, mutect2, varscan2
- LNPK | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99770044; called by muse, mutect2, varscan2
- LPGAT1 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as COSV100878091; called by muse, mutect2, varscan2
- LRFN1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99952776; called by muse, mutect2, varscan2
- LRIF1 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100870816; called by muse, mutect2, varscan2
- LRP12 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs766182789, COSV52627506; called by muse, mutect2, varscan2
- LRRC25 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV100170472; called by muse, mutect2, varscan2
- LSM10 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.994); catalogued as COSV100239992; called by muse, mutect2, varscan2
- MAGI1 | c.3649C>T p.R1217C (on ENST00000402939 / NM_001033057.2; = p.T1274= on NM_015520.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV58344413; called by muse, mutect2, varscan2
- MAGI3 | c.3515G>A p.S1172N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.206); catalogued as rs1235175411, COSV100288492; called by muse, mutect2
- MAML1 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs888518311, COSV52985126; called by muse, mutect2, varscan2
- MAP1A | c.2947C>T p.R983W | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760561360, COSV55813786; called by muse, mutect2, varscan2
- MAPK1 | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53186212, COSV53189470, COSV99307883; called by muse, mutect2
- MAPK8IP1 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394463681, COSV53797726; called by muse, mutect2
- MAPK8IP3 | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1224362476, COSV99167802; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3611T>A p.I1204N | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99167805; called by muse, mutect2, varscan2
- MBOAT7 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762705882, COSV55474711, COSV55477801; called by muse, mutect2, varscan2
- MCM3AP | c.4786C>T p.R1596C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs768179278, COSV99386643; called by muse, mutect2, varscan2
- MCOLN1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs199685178, COSV51176270; called by muse, mutect2, varscan2
- MDN1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs757957054, COSV65520492; called by muse, mutect2, varscan2
- MED12 | c.5729G>A p.R1910H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.397); catalogued as COSV100376948; called by muse, mutect2
- MED23 | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs151337645; called by muse, mutect2, varscan2
- MEGF8 | c.3688C>T p.L1230F (on ENST00000251268 / NM_001271938.2; = p.L1163F on NM_001410.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV99235197; called by muse, mutect2
- METTL24 | c.435G>C p.M145I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV100133219; called by muse, mutect2
- MGAT4B | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762638088, COSV99482133; called by muse, mutect2, varscan2
- MIB2 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1216356615, COSV61542719; called by muse, mutect2
- MIEN1 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99507295; called by muse, mutect2, varscan2
- MKI67 | c.9536C>T p.A3179V | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748615127, COSV64072570; called by muse, mutect2, varscan2
- MLF2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs751508294, COSV52571090; called by muse, mutect2, varscan2
- MMP12 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200973192, COSV100404873; called by muse, mutect2, varscan2
- MMP15 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.823); catalogued as rs368255301; called by muse, mutect2, varscan2
- MMRN2 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs778253708, COSV64400825; called by muse, mutect2, varscan2
- MOS | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV100322779; called by muse, mutect2, varscan2
- MOSPD1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100887823; called by muse, mutect2
- MROH2B | c.3949G>A p.A1317T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV68186985; called by muse, mutect2, varscan2
- MRPS2 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99613344; called by muse, mutect2
- MRTFA | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.112); catalogued as rs1179946623, COSV100843931; called by muse, mutect2, varscan2
- MSX1 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101235662; called by muse, mutect2, varscan2
- MTA1 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as rs587675929, COSV58755474; called by muse, mutect2, varscan2
- MTRR | c.483T>C p.G161= (on ENST00000264668; = p.G134= on NM_002454.3 and 4 other RefSeq transcripts) | Splice Region (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99241481; called by muse, mutect2
- MUC3A | c.8296A>G p.T2766A | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV100114267; called by muse, mutect2, varscan2
- MUSK | c.753+4_753+7del p.X251_splice | Splice Site (DEL) | VAF 11/75 reads (15%) | catalogued as rs1302421303; called by mutect2, pindel, varscan2
- MUTYH | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs146044717; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYH1 | c.2666del p.N889Mfs*24 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as rs776259351; called by mutect2, pindel
- MYH1 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1296768683, COSV99875363; called by muse, mutect2, varscan2
- MYH14 | c.2408T>A p.V803D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99222196; called by muse, mutect2, varscan2
- MYH15 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs376553191, COSV56321695; called by muse, mutect2, varscan2
- MYH4 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55112725; called by muse, mutect2, varscan2
- MYLIP | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100785935; called by muse, mutect2, varscan2
- MYO10 | c.4142G>T p.R1381M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99945012; called by muse, mutect2, varscan2
- MYO15A | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as rs747175448, COSV52756546; called by muse, mutect2, varscan2
- MYO3A | c.2581T>C p.S861P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99778959; called by muse, mutect2, varscan2
- MYO3A | c.4811G>A p.R1604H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99392867; called by muse, mutect2, varscan2
- MYRIP | c.2527G>T p.G843C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV100218689; called by muse, mutect2
- NAV1 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1160906806, COSV99818509; called by muse, mutect2, varscan2
- NBEA | c.3143T>C p.V1048A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100078271; called by muse, mutect2, varscan2
- NBEAL1 | c.7094A>G p.D2365G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV101355433; called by muse, mutect2, varscan2
- NCKAP5 | c.934G>C p.A312P | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV100490901; called by muse, mutect2
- NCOR2 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.402); catalogued as rs199761768, COSV100657078; called by muse, mutect2, varscan2
- NCSTN | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1463308762, COSV99666957; called by muse, mutect2, varscan2
- NDFIP1 | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV99551067; called by muse, mutect2, varscan2
- NDST3 | c.2072T>A p.I691N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99630023; called by muse, mutect2, varscan2
- NEDD4 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100163513; called by muse, mutect2, varscan2
- NEK4 | c.1528A>T p.I510F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99237400; called by muse, mutect2, varscan2
- NELL2 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773375620, COSV100419154; called by muse, mutect2, varscan2
- NF1 | c.5446G>T p.E1816* (on ENST00000358273 / NM_001042492.3; = p.E1795* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as COSV62212443; called by muse, mutect2, varscan2
- NFATC1 | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99501128; called by muse, mutect2, varscan2
- NINL | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1036447484, COSV53998889; called by muse, varscan2
- NINL | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs369528838, COSV54007058; called by muse, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as rs111948120; called by pindel, varscan2
- NKD1 | c.385T>A p.S129T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99194017; called by muse, mutect2, varscan2
- NKX2-5 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61298489; called by muse, mutect2, varscan2
- NLRP12 | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV100145051; called by muse, mutect2, varscan2
- NOTCH3 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as rs756520455, COSV54641571; called by muse, mutect2, varscan2
- NPHP1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV100337922; called by muse, mutect2, varscan2
- NR3C2 | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV100678836; called by muse, mutect2, varscan2
- NRDE2 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs762627864, COSV62962748, COSV62964110; called by muse, mutect2, varscan2
- NRP2 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99783824; called by muse, mutect2
- NT5C2 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.981); catalogued as COSV100583410; called by muse, mutect2, varscan2
- NTRK2 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV99453913; called by muse, mutect2, varscan2
- NUAK1 | c.798C>A p.S266R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99776809; called by muse, mutect2, varscan2
- NUCB1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs749759537, COSV54385108; called by muse, mutect2, varscan2
- NUFIP1 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100997982; called by muse, mutect2, varscan2
- NUP62 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as COSV100351889; called by muse, mutect2, varscan2
- NUP98 | c.4190G>A p.R1397H (on ENST00000359171 / NM_001365126.1; = p.R1380H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201757730, COSV61428960; called by muse, mutect2, varscan2
- OBSCN | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs769679322, COSV99475404; called by muse, mutect2, varscan2
- OCA2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs201291702, COSV100667252; called by muse, mutect2, varscan2
- OCIAD1 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as rs1244944349, COSV51900389; called by muse, mutect2, varscan2
- ODF3L1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100150740; called by muse, mutect2, varscan2
- OGG1 | c.908T>C p.F303S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99844655; called by muse, mutect2, varscan2
- OGT | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65480421; called by muse, mutect2, varscan2
- OMP | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); catalogued as rs782632842, COSV53686583; called by muse, mutect2, varscan2
- OR10G4 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs768736757, COSV100304762, COSV57978723; called by muse, mutect2, varscan2
- OR2G2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100189673, COSV60740033; called by muse, mutect2, varscan2
- OR2G6 | c.502dup p.L168Pfs*13 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | catalogued as rs1558372337; called by mutect2, pindel, varscan2
- OR2Y1 | c.415del p.H139Ifs*16 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as COSV57136178; called by mutect2, pindel, varscan2
- OR4F15 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100173856; called by muse, mutect2, varscan2
- OR4P4 | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV100111651; called by muse, mutect2, varscan2
- OR51B6 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as rs755339032, COSV66513328, COSV66513857; called by muse, mutect2
- OR51V1 | c.857T>A p.F286Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100343307; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR5H2 | c.698del p.K233Rfs*7 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV62349977; called by mutect2, pindel, varscan2
- OR6F1 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV100128869, COSV100129051; called by muse, mutect2, varscan2
- OR7A5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs143093089, COSV100457664, COSV59234008; called by muse, mutect2, varscan2
- OSBPL9 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as rs1347898548, COSV100543147; called by muse, mutect2, varscan2
- OTOGL | c.1043A>T p.D348V (on ENST00000547103; = p.D339V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101509080; called by muse, mutect2, varscan2
- OXCT2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV59594230; called by muse, mutect2, varscan2
- OXSR1 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as COSV100309265; called by muse, mutect2, varscan2
- P2RX3 | c.1057T>C p.Y353H | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99628455; called by muse, mutect2, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 16/107 reads (15%) | catalogued as rs782429503; called by mutect2, pindel, varscan2
- PAFAH1B1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV101250356; called by muse, mutect2, varscan2
- PAK3 | c.811+2T>C p.X271_splice (on ENST00000262836 / NM_001324328.2; = p.X256_splice on NM_002578.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99456875; called by muse, mutect2, varscan2
- PALD1 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99698115; called by muse, mutect2, varscan2
- PALM | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs771587894, COSV99214385; called by muse, mutect2, varscan2
- PAMR1 | c.1978A>G p.I660V (on ENST00000619888 / NM_001001991.3; = p.I677V on NM_015430.4) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs1280937095, COSV99552355; called by muse, mutect2, varscan2
- PANK3 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53322978, COSV99496260; called by muse, mutect2, varscan2
- PAPPA2 | c.3010G>A p.D1004N | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100867732; called by muse, mutect2, varscan2
- PARP3 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as rs368862832; called by muse, mutect2, varscan2
- PCDHA11 | c.1385T>C p.F462S | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV100249006; called by muse, mutect2, varscan2
- PCDHA5 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as COSV65349028, COSV65350662; called by muse, mutect2, varscan2
- PCDHA8 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.823); catalogued as rs782667421, COSV65334944; called by muse, mutect2, varscan2
- PCDHA9 | c.2095T>C p.Y699H | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100969278; called by muse, mutect2
- PCDHB1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs1554267105, COSV100128090; called by muse, mutect2, varscan2
- PCDHB15 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV50859859; called by muse, mutect2, varscan2
- PCDHB2 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99164533; called by muse, varscan2
- PCDHB9 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs1408461979; called by muse, mutect2, varscan2
- PCDHGA9 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.035); catalogued as COSV53897324; called by muse, mutect2, varscan2
- PCDHGB3 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV54043446, COSV99534093; called by muse, mutect2, varscan2
- PCLO | c.14476A>G p.K4826E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100429679; called by muse, mutect2, varscan2
- PCNT | c.5345del p.G1782Afs*21 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV64025521; called by mutect2, pindel, varscan2
- PDE4A | c.2360G>A p.G787D (on ENST00000380702 / NM_001111307.2; = p.G548D on NM_006202.3) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV99533875; called by muse, mutect2, varscan2
- PDGFRL | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99286259; called by muse, mutect2, varscan2
- PDS5B | c.1856+1G>T p.X619_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100220730; called by muse, mutect2
- PEAR1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs139444602; called by muse, mutect2
- PEG3 | c.4072G>C p.E1358Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV99688086; called by muse, varscan2
- PEG3 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV99688088; called by muse, mutect2, varscan2
- PFKL | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV62462575; called by muse, mutect2, varscan2
- PFKP | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as rs1564315256, COSV101127085; called by muse, mutect2, varscan2
- PGR | c.2750T>A p.L917* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99677806; called by muse, mutect2, varscan2
- PHF5A | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53439668, COSV53440444; called by muse, mutect2
- PHIP | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51504498; called by muse, mutect2, varscan2
- PI4KA | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55409840; called by muse, mutect2, varscan2
- PIBF1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372068016; called by muse, mutect2
- PID1 | c.511G>A p.A171T (on ENST00000354069 / NM_001330156.1; = p.A169T on NM_017933.5) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414524157, COSV62479231; called by muse, mutect2, varscan2
- PIGG | c.1711G>A p.V571M (on ENST00000453061 / NM_001127178.3; = p.V563M on NM_017733.4) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs770091281, COSV56316300; called by muse, mutect2, varscan2
- PIK3R2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs763448968, COSV99717297; called by muse, mutect2, varscan2
- PITX2 | c.644A>G p.N215S (on ENST00000354925 / NM_001204397.1; = p.N222S on NM_000325.6) | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100146245; called by muse, mutect2
- PKHD1 | c.6121+1G>A p.X2041_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100582170; called by muse, mutect2, varscan2
- PLA2G5 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs538789160, COSV100908212; called by muse, mutect2, varscan2
- PLCB3 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99657258; called by muse, mutect2, varscan2
- PLCB4 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53805715; called by mutect2, varscan2
- PLCH2 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369356142; called by muse, mutect2, varscan2
- PLEKHB2 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.703); catalogued as rs1363991594, COSV99301588; called by muse, mutect2
- PLEKHG4 | c.1193del p.G398Afs*4 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs753797464; called by mutect2, pindel
- PLIN4 | c.2314G>A p.D772N (on ENST00000301286; = p.D787N on NM_001367868.2) | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1278802369, COSV100012984; called by muse, mutect2
- PLOD1 | c.2056A>T p.N686Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99538009; called by muse, mutect2, varscan2
- PLXNC1 | c.1589G>A p.R530K | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99312741; called by muse, mutect2, varscan2
- POGK | c.817A>G p.M273V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV100902442; called by muse, mutect2, varscan2
- POLH | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV100947711; called by muse, mutect2, varscan2
- PPARGC1B | c.2896A>T p.K966* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100494600; called by muse, mutect2
- PPAT | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99947142; called by muse, mutect2, varscan2
- PPCS | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1482478128, COSV65333597; called by muse, varscan2
- PPCS | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as rs375090300; called by muse, varscan2
- PPEF1 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV100583640; called by muse, mutect2, varscan2
- PPHLN1 | c.1079A>T p.D360V | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV99871617; called by muse, mutect2, varscan2
- PPIC | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120556; called by muse, mutect2, varscan2
- PPP2CA | c.928T>C p.*310Qext*1 | Nonstop Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101522721; called by muse, mutect2
- PPP2R1A | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770861676, COSV59045376; called by muse, mutect2, varscan2
- PRAMEF19 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879225837; called by muse, mutect2
- PRC1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs570196720, COSV62695510; called by muse, mutect2, varscan2
- PRDX6 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV100458441; called by muse, mutect2, varscan2
- PREX2 | c.3223A>G p.N1075D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.045); catalogued as rs556672943, COSV55765149; called by muse, mutect2, varscan2
- PRMT9 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100482073; called by muse, mutect2, varscan2
- PRNP | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.576); catalogued as COSV101057242; called by muse, mutect2, varscan2
- PROC | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs368520760; called by muse, mutect2, varscan2
- PROCA1 | c.868G>A p.A290T (on ENST00000439862 / NM_001366301.1; = p.A262T on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.06); catalogued as COSV99972609; called by muse, mutect2, varscan2
- PRPF40B | c.143C>T p.A48V (on ENST00000380281; = p.A42V on NM_012272.3) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs149751647; called by muse, mutect2, varscan2
- PRR12 | c.1861G>A p.A621T (on ENST00000615927; = p.A1442T on NM_020719.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101330605; called by muse, mutect2, varscan2
- PRR30 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99574378; called by muse, mutect2, varscan2
- PSD2 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as rs768646630, COSV51214628; called by muse, mutect2, varscan2
- PSD4 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as COSV55528616; called by muse, mutect2
- PSD4 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1160238188, COSV99830951; called by muse, mutect2, varscan2
- PSEN2 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422957; called by muse, mutect2, varscan2
- PSG1 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99739368; called by muse, mutect2, varscan2
- PSG3 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100548802; called by muse, mutect2, varscan2
- PTPN11 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; called by muse, mutect2, varscan2
- PTPN13 | c.7058G>T p.R2353M (on ENST00000411767 / NM_080683.3; = p.R2334M on NM_006264.3) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100364407; called by muse, mutect2, varscan2
- PTPN5 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1037962955, COSV62125787; called by muse, mutect2, varscan2
- PTPRE | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1430763431, COSV54560956; called by muse, mutect2, varscan2
- PTPRT | c.2246del p.G749Afs*2 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as COSV100624254; called by mutect2, pindel, varscan2
- PTPRU | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112199; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs755727862; called by mutect2, varscan2
- QKI | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs752167117, COSV99274648; called by muse, mutect2, varscan2
- QRICH2 | c.3104G>A p.G1035E | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99428954; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2217T>G p.S739R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.52); catalogued as COSV100741104; called by muse, mutect2
- RAC1 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100640973, COSV61821556; called by muse, mutect2, varscan2
- RAC2 | c.294C>G p.F98L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV50774045, COSV99969421; called by muse, mutect2, varscan2
- RAI1 | c.4666C>T p.R1556C | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs925201797, COSV99883694; called by muse, mutect2, varscan2
- RALYL | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV101569113; called by muse, mutect2, varscan2
- RAPSN | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.253); catalogued as COSV100100056; called by muse, mutect2, varscan2
- RASAL3 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs866548350, COSV99483901; called by muse, mutect2, varscan2
- RASGRF2 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99428630; called by muse, mutect2
- RBM15 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873417; called by muse, mutect2, varscan2
- RBM25 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99998558; called by muse, mutect2
- RBSN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1005442434, COSV53792217; called by muse, mutect2, varscan2
- RECQL5 | c.2615G>A p.R872H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs372355133; called by muse, mutect2, varscan2
- RELL1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.35); catalogued as COSV58454723; called by muse, mutect2, varscan2
- REN | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769746703, COSV65818467; called by muse, mutect2, varscan2
- RESF1 | c.5047G>A p.A1683T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100440238; called by muse, mutect2, varscan2
- RFX4 | c.655G>A p.A219T (on ENST00000392842 / NM_213594.3; = p.A125T on NM_032491.6) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV99985576; called by muse, mutect2
- RHOBTB2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52570645; called by muse, mutect2, varscan2
- RIN2 | c.608A>T p.Y203F (on ENST00000255006 / NM_001242581.1; = p.Y154F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.987); catalogued as COSV99656799; called by muse, mutect2
- RNASE13 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100409514; called by muse, mutect2, varscan2
- RNASE9 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100141167; called by muse, mutect2, varscan2
- RNF13 | c.606+2T>C p.X202_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100694046; called by muse, mutect2, varscan2
- ROCK1 | c.691T>C p.C231R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV101296292; called by muse, mutect2, varscan2
- RPS6KA2 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776642914, COSV55820234; called by muse, mutect2, varscan2
- RRP8 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV99601845; called by muse, mutect2, varscan2
- RSF1 | c.1158del p.K386Nfs*6 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs1451848162, COSV100408029; called by mutect2, pindel, varscan2
- RTEL1 | c.1678_1680del p.F560del | In Frame Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs779176651; called by pindel, varscan2
- SAFB | c.2451del p.R818Dfs*24 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV99412707, COSV99412757; called by mutect2, pindel
- SAMD4A | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs370029371; called by muse, mutect2, varscan2
- SAP130 | c.2375A>G p.D792G | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV99384397; called by muse, mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCMH1 | c.1704T>A p.N568K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100401501; called by muse, mutect2, varscan2
- SCMH1 | c.613C>T p.R205* (on ENST00000326197 / NM_001031694.2; = p.R158* on NM_012236.4) | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as rs1476104286, COSV58239451; called by muse, mutect2, varscan2
- SCN2B | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.903); catalogued as rs878854712, COSV54050889; ClinVar: uncertain significance; called by mutect2, varscan2
- SCN8A | c.4893C>G p.I1631M | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61993591; called by muse, mutect2
- SCN9A | c.4883A>G p.K1628R (on ENST00000303354; = p.K1617R on NM_002977.3) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as rs1398222209, COSV100312065; called by muse, mutect2
- SCRN2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV51636252; called by muse, mutect2, varscan2
- SCUBE1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs372473028, COSV99297941; called by muse, mutect2, varscan2
- SCX | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1304826334; called by muse, mutect2, varscan2
- SEC14L1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs767606459, COSV66722028; called by muse, mutect2, varscan2
- SEC14L5 | c.1863del p.S622Afs*14 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs764657044; called by mutect2, pindel
- SEC23B | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147135162; called by muse, mutect2, varscan2
- SEC23IP | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956799; called by muse, mutect2, varscan2
- SECISBP2 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358114; called by muse, mutect2, varscan2
- SEZ6L2 | c.929G>A p.G310D (on ENST00000308713 / NM_001114099.3; = p.G240D on NM_012410.4) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752413264, COSV58104348; called by muse, mutect2, varscan2
- SF3A3 | c.530G>T p.R177M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as COSV100885621; called by muse, mutect2, varscan2
- SFTPD | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100954505; called by muse, mutect2, varscan2
- SGF29 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100187085; called by muse, mutect2, varscan2
- SGF29 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1567294084, COSV100186993; called by muse, mutect2
- SH3BP2 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.989); catalogued as COSV100696891; called by muse, mutect2
- SH3RF3 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1047066921, COSV100512551; called by muse, mutect2, varscan2
- SHKBP1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as rs746964118, COSV52538561; called by muse, mutect2, varscan2
- SHROOM2 | c.3692G>A p.C1231Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs1355939090, COSV101098369; called by muse, mutect2, varscan2
- SLC10A2 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99807784; called by muse, mutect2, varscan2
- SLC10A6 | c.326del p.G109Afs*21 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | catalogued as rs753933531, COSV56721805; called by mutect2, pindel, varscan2
- SLC12A4 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs758204627, COSV100311502; called by muse, mutect2, varscan2
- SLC12A5 | c.3371T>G p.V1124G (on ENST00000454036 / NM_001134771.2; = p.V1101G on NM_020708.5) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99275366; called by muse, mutect2, varscan2
- SLC15A1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs770486047, COSV64732272; called by muse, mutect2, varscan2
- SLC16A7 | c.786del p.F262Lfs*39 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV53899988; called by mutect2, pindel, varscan2
- SLC16A8 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100259988; called by muse, mutect2
- SLC1A2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs138860120; called by muse, mutect2, varscan2
- SLC22A1 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs376456834, COSV61451602; called by muse, mutect2, varscan2
- SLC22A7 | c.1600A>G p.T534A (on ENST00000372585 / NM_153320.2; = p.T532A on NM_006672.3) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1226668368, COSV99240230; called by muse, mutect2
- SLC23A2 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs1299331518, COSV100594920, COSV57775097; called by muse, mutect2, varscan2
- SLC25A12 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs927242874, COSV99784814; called by muse, mutect2, varscan2
- SLC26A7 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs780024221, COSV99403000; called by muse, mutect2, varscan2
- SLC2A14 | c.542T>A p.L181H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100533694; called by muse, mutect2, varscan2
- SLC35C1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs748793953, COSV100029354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC44A4 | c.431dup p.N144Kfs*55 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | catalogued as rs764603659; called by pindel, varscan2
- SLC49A3 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100448403; called by muse, mutect2, varscan2
- SLC4A10 | c.1280T>A p.L427H (on ENST00000446997 / NM_001354461.2; = p.L397H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763119; called by muse, mutect2, varscan2
- SLC4A3 | c.146A>G p.D49G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs387907529, COSV99812627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A11 | c.1114G>T p.G372W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762691; called by muse, mutect2
- SLC6A16 | c.1546A>G p.I516V | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as rs1248913989, COSV100242642; called by muse, mutect2
- SLC6A7 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV100046106; called by muse, mutect2, varscan2
- SLC8A1 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100245356; called by muse, mutect2, varscan2
- SLC9A2 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs199943468, COSV52135225, COSV99296029; called by muse, mutect2, varscan2
- SLC9B1 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99599385; called by muse, mutect2
- SLC9B2 | c.173del p.K58Sfs*15 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV100294119; called by mutect2, pindel
- SLC9C1 | c.2014del p.S672Hfs*9 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs761139813; called by mutect2, pindel, varscan2
- SLCO1B3 | c.2085G>A p.M695I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV53946832, COSV53947047; called by muse, mutect2, varscan2
- SLFN12 | c.713T>G p.F238C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100512974; called by muse, mutect2, varscan2
- SLIT1 | c.4168C>T p.Q1390* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99820944; called by muse, mutect2
- SMCHD1 | c.3187G>A p.G1063S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55264754, COSV99861115; called by muse, mutect2
- SMPD1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV100192533; called by muse, mutect2, varscan2
- SNUPN | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV57947788; called by muse, mutect2
- SNX17 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs772349518, COSV52006259; called by muse, mutect2, varscan2
- SON | c.7135A>T p.I2379F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV99277436; called by muse, mutect2
- SOX30 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99398290; called by muse, mutect2
- SOX9 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99818286; called by muse, mutect2, varscan2
- SP6 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV100646972; called by muse, mutect2
- SPAM1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532636427, COSV56144434; called by muse, mutect2, varscan2
- SPANXB1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.12); catalogued as rs1394966113; called by muse, mutect2
- SPARCL1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.212); catalogued as COSV99215391; called by muse, mutect2
- SPATA20 | c.721G>A p.A241T (on ENST00000356488 / NM_001258372.1; = p.A257T on NM_022827.4) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs113193422; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEN | c.10595T>C p.V3532A | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.508); catalogued as COSV100998989; called by muse, mutect2, varscan2
- SPINDOC | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.661); catalogued as rs763536245, COSV99588510; called by muse, mutect2, varscan2
- SPOCK3 | c.93del p.R32Gfs*34 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs34708130, COSV100692271; called by mutect2, pindel, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 24/162 reads (15%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPPL2C | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769994819, COSV100233980; called by muse, mutect2, varscan2
- SPTBN1 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.268); catalogued as COSV100442119; called by muse, mutect2, varscan2
- SPTBN1 | c.4619G>A p.R1540H | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1284166106, COSV61686618; called by muse, mutect2, varscan2
- SRMS | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs140476273; called by muse, mutect2, varscan2
- SRPK3 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs782627381, COSV99473051; called by muse, mutect2, varscan2
- SRRM4 | c.1106C>A p.A369D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs142472990, COSV57429203; called by muse, mutect2, varscan2
- SS18 | c.880+2T>C p.X294_splice | Splice Site (SNP) | VAF 7/82 reads (9%) | catalogued as COSV52261141; called by muse, mutect2
- SSH2 | c.4239dup p.R1414Tfs*8 | Frame Shift Ins (INS) | VAF 14/146 reads (10%) | catalogued as rs1567821813; called by mutect2, pindel
- STAB2 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101185769; called by muse, mutect2
- STAM2 | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99812927, COSV99813342; called by muse, mutect2
- STARD3 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1045873498, COSV99988276; called by muse, mutect2, varscan2
- STOX2 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100408535; called by muse, mutect2, varscan2
- STX10 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.395); catalogued as COSV99456895; called by muse, mutect2, varscan2
- STX6 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs770420386, COSV99275553; called by muse, mutect2
- SULF2 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs768084550, COSV63413665; called by muse, mutect2, varscan2
- SULT1A1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs753675433; called by muse, mutect2
- SUPT5H | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs374491321; called by muse, mutect2, varscan2
- SYNE1 | c.6674G>A p.S2225N (on ENST00000367255 / NM_182961.4; = p.S2232N on NM_033071.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV99557957; called by muse, mutect2, varscan2
- SYNJ2 | c.2743C>A p.L915I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100840103; called by muse, mutect2, varscan2
- TAF5L | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs569704813, COSV51092439, COSV99272928; called by muse, mutect2, varscan2
- TAGAP | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs376487437; called by muse, mutect2, varscan2
- TANC1 | c.2077A>G p.S693G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs750990055, COSV99713402; called by muse, mutect2, varscan2
571 further variants in this file (251 protein-altering or splice-affecting, 295 silent, 25 other) are not listed here.
